Somatic mutation profile of tumor specimen 0DHOJ8 from CCDI case PBBUBP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 13.4 years (4,879 days).
Specimen 0DHOJ8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0cbcbd84-8f92-486c-9189-2f819fbbeea6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHOGU (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/74f987fb-a467-4da7-955d-5614f26960c2

The open-access MAF lists 5 somatic variants for this specimen: 2 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 3, Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACP1 | c.37T>A p.C13S | Missense Mutation (SNP) | VAF 36/578 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as COSV99681892; called by muse, mutect2
- MAFF | c.421A>C p.K141Q | Missense Mutation (SNP) | VAF 33/277 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- CSF2RA | c.1125+298C>A | Intron (SNP) | VAF 16/114 reads (14%) | called by muse, varscan2
- RPSA | c.252+110_252+111insC | Intron (INS) | VAF 14/154 reads (9%) | catalogued as rs1373065411; called by mutect2, varscan2
- SLC50A1 | c.158+118T>A | Intron (SNP) | VAF 18/136 reads (13%) | catalogued as rs1014170885; called by muse, varscan2
